Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KL, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KL-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology

Page 1 of 4

REPORT Tel:

Clinical Consultant & Location

Sex

Unit No

This Copy For:

SPECIMEN

LEFT ENUCLEATED GLOBE

CLINICAL DETAILS

Left melanoma.

Tumour size: 17.7 x 17.3mm, thickness 8.1mm

MACROSCOPIC DESCRIPTION

A fresh intact left globe.

Dimensions: Axial 23mm, Horizontal 23.5mm, Vertical 23mm

Cornea: Horizontal 12mm, Vertical 11mm

Optic nerve

Length 15.5mm, Diameter 4mm

Anterior chamber: IOL in situ.

On trans-illumination, there is a large infero-lateral shadow up to 16mm in diameter extending from ciliary body posteriorly.

Plane of section: Oblique.

Intraocular description:

On opening, a large solitary pigmented choroidal mass is confirmed.

Tumour size

LBD 17mm, Height 7mm

MICROSCOPY

Sections show a partially pigmented choroidal melanoma (adjacent to ora serrata). Tumour is of mixed cell type but includes only a minor epithelioid cell component (less than 15%). Tumour cells express Melan-A and HSP 27 (score 2).

The number of mitosis is small, approximately 2/40 high

ICD-O-3
Melanoma, epithelioid & spindle
cell mixed 8776/3
Site @ Choroid C69.3
J 1/17/14

Reported:

Pathologist:

Electronically Verified:

[page 2 of 2]
Department of Pathology

Page 2 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	[REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

power fields. The microvasculature of the melanoma is prominent, and closed loops are not present in the planes of sections. The lymphocytic infiltrate within the tumour is minimal. Tumour necrosis is not seen. Bruch's membrane appears focally breached in the sections examined. There is no tumour extension through optic nerve or vortex veins examined. Tumour, however, focally infiltrates adjacent sclera along a vascular channel. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is deep. The iris shows no significant abnormality but the ciliary body appears atrophic with hyalinisation of ciliary processes. Residual lens capsule with attached small portion of cataractuous lens matter is present. Retina overlying the tumour is slightly atrophic. Focal serous retinal detachment is seen away from the tumour.

DIAGNOSIS

Left eye, enucleation: Choroidal melanoma of mixed cell type with focal scleral infiltration.

SUMMARY

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	1= No closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	2 /40 HPF
DIFFUSE MELANOMA	No
SPREAD	2= Intra-scleral

Reported:

Pathologist:

Electronically Verified:

Criteria	11/6/13	Yes	No

Source: NCI Genomic Data Commons file 56c60143-c05a-4fc3-b03d-05b762f74339 (TCGA-VD-A8KL.6B270354-A072-4FB0-8AB1-CEBECFF87DF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).